Somatic mutation profile of tumor specimen TCGA-P5-A5EV-01A (aliquot TCGA-P5-A5EV-01A-11D-A27K-08) from TCGA case TCGA-P5-A5EV, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 39.2 years (14,310 days).
Specimen TCGA-P5-A5EV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d93b867d-3419-4ad5-91b0-144b045ec698.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A5EV-10A (Blood Derived Normal), aliquot TCGA-P5-A5EV-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95454aeb-0f28-40fa-918a-744e3af6a3fd

The open-access MAF lists 79 somatic variants for this specimen: 64 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 13, Nonsense Mutation 2, Intron 1, Splice Region 1, 5'UTR 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 26/64 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAM22 | c.2008C>G p.P670A | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV55992961; called by muse, mutect2, varscan2
- ADCY1 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.217); catalogued as COSV52034039; called by muse, mutect2, varscan2
- ADGRF5 | c.2052G>C p.Q684H | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.701); catalogued as COSV51942198; called by muse, mutect2, varscan2
- AIPL1 | c.465+1G>A p.X155_splice | Splice Site (SNP) | VAF 56/76 reads (74%) | catalogued as rs887335730, CS078187, CS140186, COSV51509348; called by muse, mutect2, varscan2
- ANXA7 | c.552C>G p.N184K (on ENST00000372919 / NM_001320880.2; = p.N162K on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV65824710; called by muse, mutect2
- AP5S1 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV55693659; called by muse, mutect2, varscan2
- ARID3B | c.1663C>G p.P555A (on ENST00000622429 / NM_001307939.1; = p.P554A on NM_006465.4) | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV60559598; called by muse, mutect2
- ATP10A | c.2867C>G p.S956C | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.684); catalogued as COSV100791303, COSV63526493; called by muse, varscan2
- ATP12A | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.575); catalogued as COSV54524817, COSV99517269; called by muse, mutect2, varscan2
- ATRX | c.3710C>G p.S1237* | Nonsense Mutation (SNP) | VAF 49/66 reads (74%) | catalogued as COSV64885657; called by muse, mutect2, varscan2
- BRD1 | c.849G>C p.K283N | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53462610; called by muse, mutect2
- BTNL8 | c.749G>C p.G250A | Missense Mutation (SNP) | VAF 112/295 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV51462580; called by muse, mutect2, varscan2
- CCDC91 | c.713C>G p.S238C | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV60345150, COSV60350364; called by muse, mutect2, varscan2
- CD151 | c.603C>G p.I201M | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58991316; called by muse, mutect2
- CD163L1 | c.3484G>A p.G1162R | Missense Mutation (SNP) | VAF 150/359 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs779749979, COSV58012340; called by muse, mutect2, varscan2
- CHSY1 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs756747714, COSV54256644; called by muse, mutect2, varscan2
- COL7A1 | c.1723G>A p.V575M | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60404485; called by muse, mutect2, varscan2
- DDI1 | c.619G>C p.D207H | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56397452; called by muse, mutect2, varscan2
- DLG5 | c.1990A>T p.I664F | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV64950395; called by muse, mutect2, varscan2
- EXOC4 | c.2601C>G p.I867M | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV54127564; called by muse, mutect2, varscan2
- FARP1 | c.2879G>C p.C960S | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.722); catalogued as COSV60350788; called by muse, mutect2
- FMN2 | c.2228C>T p.S743L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1397813836, COSV60424392; called by muse, mutect2, varscan2
- GHITM | c.102G>C p.K34N | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as COSV64539409; called by muse, mutect2, varscan2
- GIGYF1 | c.1723G>C p.V575L | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV51947649; called by muse, mutect2, varscan2
- GPRC5C | c.1397C>T p.A466V (on ENST00000652232; = p.A421V on NM_018653.4) | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as rs144073326; called by muse, mutect2
- HEBP1 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs76698360; called by muse, mutect2, varscan2
- HGD | c.1311C>A p.N437K | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs756737699, COSV52202187; called by muse, mutect2, varscan2
- IFNAR1 | c.248C>G p.T83S | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV54254969; called by muse, mutect2
- KBTBD11 | c.1437G>C p.E479D | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.767); catalogued as COSV57225037; called by mutect2, varscan2
- KIAA1549L | c.683C>G p.T228S (on ENST00000321505; = p.T525S on NM_012194.3) | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as rs1382236725, COSV55782648; called by muse, mutect2, varscan2
- LMBRD2 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as rs762650524, COSV56948565; called by muse, mutect2, varscan2
- LRRC2 | c.590G>T p.C197F | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV56129404; called by muse, mutect2
- MACF1 | c.13067C>G p.S4356C (on ENST00000372915; = p.S2289C on NM_012090.5) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV57149813; called by muse, mutect2, varscan2
- MACF1 | c.14494G>C p.E4832Q (on ENST00000372915; = p.E2765Q on NM_012090.5) | Missense Mutation (SNP) | VAF 90/274 reads (33%) | catalogued as COSV57149841; called by muse, mutect2, varscan2
- MAF | c.31G>C p.D11H | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV58155415; called by muse, varscan2
- MS4A4A | c.387G>C p.L129= | Splice Region (SNP) | VAF 10/24 reads (42%) | catalogued as COSV59703981; called by muse, mutect2, varscan2
- MUC16 | c.22108C>G p.L7370V | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.281); catalogued as COSV67501775; called by muse, mutect2
- MYH4 | c.1245del p.G417Afs*121 | Frame Shift Del (DEL) | VAF 26/137 reads (19%) | catalogued as COSV99700710; called by mutect2, pindel, varscan2
- MYO1F | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 89/227 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.928); catalogued as COSV57801311; called by muse, mutect2, varscan2
- MYORG | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as rs769496749, COSV52627497; called by muse, mutect2, varscan2
- PANX2 | c.212C>G p.T71S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.942); catalogued as COSV50321151; called by muse, mutect2, varscan2
- PCDHA6 | c.1572C>G p.D524E | Missense Mutation (SNP) | VAF 90/315 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65348287; called by muse, mutect2, varscan2
- PDCD7 | c.842G>C p.C281S | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.647); catalogued as COSV52601716; called by muse, mutect2
- PEAK1 | c.4505C>G p.S1502C | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.934); catalogued as rs763070771, COSV56945034; called by muse, mutect2, varscan2
- PHB2 | c.317T>A p.L106Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54644209; called by muse, mutect2, varscan2
- POU1F1 | c.258G>C p.L86F | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV60157794; called by muse, mutect2, varscan2
- POU2F1 | c.2128C>G p.H710D (on ENST00000541643 / NM_001365848.1; = p.H733D on NM_002697.4) | Missense Mutation (SNP) | VAF 15/446 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV54826693; called by muse, mutect2
- PRR23B | c.446C>G p.A149G | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV61495128; called by muse, mutect2
- PRR35 | c.1513G>C p.G505R | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV50313668, COSV50323619; called by muse, mutect2
- PTGDR2 | c.600C>G p.N200K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57126541; called by mutect2, varscan2
- PXDN | c.3408C>G p.N1136K | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53248336; called by muse, mutect2, varscan2
- RTP5 | c.1701C>G p.I567M | Missense Mutation (SNP) | VAF 15/332 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as COSV58322402; called by muse, mutect2
- SALL3 | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV73306082, COSV73306726; called by muse, mutect2, varscan2
- SCRIB | c.610C>G p.L204V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57594747; called by muse, mutect2, varscan2
- SIGLEC6 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100585224, COSV58438093; called by muse, mutect2, varscan2
- SON | c.5501A>G p.H1834R | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as rs1279391009, COSV51672515; called by muse, mutect2
- SRSF4 | c.611G>C p.S204T | Missense Mutation (SNP) | VAF 21/244 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV65695992; called by muse, mutect2
- TSC2 | c.5135C>G p.A1712G | Missense Mutation (SNP) | VAF 74/186 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as CM961390, COSV51927592; called by muse, mutect2, varscan2
- TXNL4A | c.120G>C p.K40N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.179); catalogued as COSV54100508; called by muse, mutect2, varscan2
- UCN | c.342G>C p.Q114H | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV51992309; called by muse, mutect2, varscan2
- USP40 | c.1745A>G p.D582G | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs780862730, COSV52489852; called by muse, mutect2, varscan2
- VPS13B | c.8215C>G p.Q2739E | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1166109240, COSV62160772; called by muse, mutect2, varscan2
- ZNF697 | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.338); catalogued as COSV70284378; called by muse, mutect2, varscan2
- ABCA6 | c.1581T>C p.L527= | Silent (SNP) | VAF 43/112 reads (38%) | catalogued as COSV52646714; called by muse, mutect2, varscan2
- HOXB5 | c.582G>C p.G194= | Silent (SNP) | VAF 40/93 reads (43%) | catalogued as rs556018585, COSV53314503; called by muse, mutect2, varscan2
- KL | c.555G>C p.V185= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV66310264; called by muse, mutect2, varscan2
- LIG4 | c.2370A>G p.E790= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs748625382, COSV63598319; called by muse, mutect2, varscan2
- MUC5B | c.7722C>G p.V2574= | Silent (SNP) | VAF 92/357 reads (26%) | catalogued as COSV71596609; called by muse, mutect2, varscan2
- MYF5 | c.438T>C p.Y146= | Silent (SNP) | VAF 113/295 reads (38%) | catalogued as rs752815968, COSV57357058; called by muse, mutect2, varscan2
- MYO5B | c.3981A>C p.G1327= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV53232628, COSV53233969; called by muse, mutect2, varscan2
- NAA40 | c.690G>C p.G230= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV58162196; called by muse, mutect2, varscan2
- NUP153 | c.2685G>A p.S895= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as rs749852957, COSV50447294; called by muse, mutect2, varscan2
- PCDH7 | c.393C>G p.V131= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100688733, COSV62344379; called by muse, mutect2, varscan2
- PFKFB3 | c.213C>G p.V71= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV57994241; called by muse, mutect2, varscan2
- SYT10 | c.1521T>C p.S507= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as COSV57346669; called by muse, mutect2, varscan2
- ZFHX3 | c.2106C>G p.V702= | Silent (SNP) | VAF 14/204 reads (7%) | catalogued as COSV51740300; called by muse, mutect2
- KCNH3 | c.-1G>C | 5'UTR (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99234665; called by muse, mutect2, varscan2
- TTN | c.10360+2254G>C | Intron (SNP) | VAF 26/102 reads (25%) | catalogued as COSV100592588, COSV60008433; called by muse, mutect2, varscan2
